Somatic mutation profile of tumor specimen TCGA-P5-A72U-01A (aliquot TCGA-P5-A72U-01A-31D-A32B-08) from TCGA case TCGA-P5-A72U, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 71.2 years (26,002 days).
Specimen TCGA-P5-A72U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5aa713b-be0e-43c9-b5f0-154c28e02499.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A72U-10A (Blood Derived Normal), aliquot TCGA-P5-A72U-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c556016-d099-40e4-bd65-cd83d9635bcf

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.1785+1G>A p.X595_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as rs145594158; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99933566; called by muse, mutect2, varscan2
- ABCC9 | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs140872303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABLIM3 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs757936962, COSV58647978; called by muse, mutect2, varscan2
- ADAMTS3 | c.2789C>A p.T930N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV99711308; called by muse, mutect2, varscan2
- CDH18 | c.351C>A p.D117E | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953299, COSV99935729; called by muse, mutect2, varscan2
- CSTF2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV63376490, COSV63376578; called by muse, mutect2, varscan2
- DTX4 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs376862310; called by mutect2, varscan2
- F2R | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs745628757, COSV100058500; called by muse, mutect2, varscan2
- GABRD | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747781422, COSV101059550; called by muse, varscan2
- GPRASP1 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100850886, COSV100851020; called by muse, mutect2
- HDX | c.1966C>A p.P656T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99947463; called by muse, mutect2, varscan2
- IDH2 | c.649_650insAGGGCA p.V217delinsEGM | In Frame Ins (INS) | VAF 24/140 reads (17%) | catalogued as COSV100343902; called by mutect2, pindel, varscan2
- KDELR2 | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99330634; called by muse, mutect2, varscan2
- LAMA3 | c.6457G>T p.A2153S (on ENST00000313654 / NM_198129.4; = p.A544S on NM_000227.6) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99335083; called by muse, mutect2, varscan2
- LRP2 | c.10002C>A p.Y3334* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99788937, COSV99790525; called by muse, mutect2, varscan2
- MAGEB4 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100975018; called by muse, mutect2, varscan2
- MX2 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100415999; called by muse, mutect2, varscan2
- MYO3A | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200209381, COSV56330720, COSV56338173; called by muse, mutect2, varscan2
- NANS | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52964905; called by muse, mutect2, varscan2
- NIBAN2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773593282, COSV100964906; called by muse, mutect2, varscan2
- NUP93 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100360317; called by muse, mutect2, varscan2
- PCDHGA3 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as rs773154186, COSV53985299; called by muse, mutect2, varscan2
- PDIA4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99618614; called by muse, mutect2
- PGAM4 | c.365C>G p.P122R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV100431033; called by muse, mutect2, varscan2
- PGR | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.048); catalogued as COSV99678534; called by muse, mutect2, varscan2
- PLCXD2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as COSV101210092, COSV67340359; called by muse, mutect2, varscan2
- PPP1R15A | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV52339938; called by muse, mutect2, varscan2
- PROKR1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs753677083, COSV58136486; called by muse, mutect2, varscan2
- RANBP2 | c.7123G>A p.D2375N | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99312409; called by muse, mutect2, varscan2
- RIC8A | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs374226459; called by muse, mutect2, varscan2
- SGSM2 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758797068, COSV99280240; called by muse, mutect2, varscan2
- SNX31 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201556002, COSV61264343; called by muse, mutect2, varscan2
- SP140 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763966598, COSV59451528; called by muse, mutect2, varscan2
- SREBF2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs755066563, COSV100761447; called by muse, mutect2, varscan2
- TAB3 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); catalogued as COSV99916355; called by muse, mutect2, varscan2
- TFAP2B | c.235T>G p.Y79D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99540339; called by muse, mutect2, varscan2
- THRB | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99769541; called by muse, mutect2, varscan2
- TMEM132D | c.1607A>G p.N536S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV101242909; called by muse, mutect2, varscan2
- ZDHHC13 | c.1769G>A p.C590Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.597); catalogued as COSV101239977; called by muse, mutect2, varscan2
- ZNF135 | c.967G>A p.E323K (on ENST00000313434 / NM_001289401.2; = p.E335K on NM_003436.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as rs762866748, COSV57879867, COSV57882102; called by muse, mutect2, varscan2
- MED13L | c.5314dup p.T1772Nfs*10 | Frame Shift Ins (INS) | VAF 21/100 reads (21%) | called by mutect2, pindel, varscan2
- CUZD1 | c.1257C>T p.N419= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100158857; called by muse, mutect2, varscan2
- DKK2 | c.420G>A p.P140= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs372180616; called by muse, mutect2, varscan2
- DMBT1 | c.6411C>T p.C2137= (on ENST00000338354 / NM_001377530.1; = p.C1380= on NM_004406.3) | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs779346078, COSV57552408; called by muse, mutect2, varscan2
- EGFL7 | c.120C>T p.V40= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV100451992; called by muse, mutect2, varscan2
- ITPR3 | c.3171C>T p.R1057= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs774110911, COSV100967513; called by muse, mutect2, varscan2
- NLRP12 | c.831G>A p.A277= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs371391087; called by muse, mutect2, varscan2
- NPY5R | c.774T>A p.T258= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100642812; called by muse, mutect2
- PCLO | c.8868G>A p.Q2956= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV100433688; called by muse, mutect2, varscan2
- PLCB1 | c.3537C>T p.H1179= | Silent (SNP) | VAF 50/209 reads (24%) | catalogued as rs763992421, COSV100571326; called by muse, mutect2, varscan2
- RCBTB1 | c.942G>A p.R314= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs1454398459, COSV99319567; called by muse, mutect2, varscan2
- RRM1 | c.1206C>T p.T402= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100331334; called by muse, mutect2, varscan2
- SH3TC1 | c.1644G>A p.G548= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1223012652, COSV99794963; called by muse, mutect2, varscan2
